Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5519, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5519-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a history of PSA value of 15, [REDACTED]. The patient also has a history of biopsy on [REDACTED] this biopsy reveals: right apex = Gleason grade 4+4 = 8; right mid = Gleason grade 4+4 = 8; right base = Gleason grade 4+3 = 7; left base = Gleason grade 4+3 = 7; left mid = Gleason grade 4+3 = 7; left apex = Gleason grade 4+4 = 8.
PRE-OP DIAGNOSIS: Prostate cancer.
POST-OP DIAGNOSIS: Same.
PROCEDURE: Radical prostatectomy.

TCGA - EJ - 5519

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -
METASTATIC CARCINOMA IN ONE OF SIX (1/6) LYMPH NODES EXAMINED.

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -
METASTATIC CARCINOMA IN TWO OF SIX (2/6) LYMPH NODES EXAMINED.

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY-DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 4 + 4 = 8 WITH TERTIARY GLEASON PATTERN 3.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 2.6 CM.
- C. THE CARCINOMA INVOLVES 70% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS ESTABLISHED EXTRACAPSULAR EXTENSION IN THE RIGHT AND LEFT POSTERIOR BASE REGIONS AND FOCALLY INVOLVES THE INKED SURGICAL MARGINS IN THESE REGIONS (SLIDES 3W, 3X, 3BB).
- E. BILATERAL SEMINAL VESICLES ARE INVOLVED BY CARCINOMA.
- F. ALL OTHER MARGINS ARE NEGATIVE FOR TUMOR.
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: p3b N1 MX.
- K. TNM HISTOLOGIC GRADE = G3-4.
- L. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC MODERATELY ACTIVE PROSTATITIS ARE NOTED.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 15
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS ✓
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	8
GLEASON 4/5 PERCENTAGE:	90%
WEIGHT OF PROSTATE:	52.81gm
TUMOR SIZE:	Maximum dimension: 2.4 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	> 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	Yes
SEMINAL VESICLE INVASION:	Yes
SURGICAL MARGIN INVOLVEMENT:	Widespread tumor involvement at margin
LYMPH NODES EXAMINED:	12
LYMPH NODES POSITIVE:	3
EXTRANODAL EXTENSION:	Unknown
T STAGE, PATHOLOGIC:	pT3b-
N STAGE, PATHOLOGIC:	pN1
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file f74763a0-ae6f-4c52-8f61-9823291937f5 (TCGA-EJ-5519.57861C52-0D80-484A-A800-65C3481327DB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).